TCGA case TCGA-33-AASD — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef6116ce-ae38-488c-b3cc-0e88ba0f1876

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 2,249 days (6.2 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2001; AJCC staging edition: 5th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 90 years or older (exact value withheld by GDC); Days to diagnosis: 1,912 days (5.2 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 1,912 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,912 days (5.2 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,249 days (6.2 years); Disease response: With Tumor.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Preoperative.

Other clinical attributes
- DLCO (% of predicted): 38.1; FEV1/FVC after bronchodilator (%): 66.9; FEV1/FVC before bronchodilator (%): 77.4; FEV1 after bronchodilator (% of reference): 82.4; FEV1 before bronchodilator (% of reference): 95.3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 84; Tobacco smoking onset year: 1950.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-33-AASD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-33-AASD-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 36; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-33-AASD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-33-AASD-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-33-AASD-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 80; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Lower; Pulmonary function test indicator: Yes; Treatment outcome first course: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,376 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 3,376 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,912 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-33-AASD-01A-11D-A400-01): tumor purity 0.69, ploidy 3.33, whole-genome doublings 1.
